TCGA case TCGA-60-2715 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f3e67161-1532-4b50-a9b5-0da80410c4d7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Vital status: Dead; Days to death: 1,075 days (2.9 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 52.0 years (18,990 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 448 days (1.2 years); Days to treatment end: 511 days (1.4 years); Number of cycles: 2; Treatment dose: 150 mg/m2; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 546 days (1.5 years); Days to treatment end: 633 days (1.7 years); Number of cycles: 4; Treatment dose: 2,204 mg; Prescribed dose: 551; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 546 days (1.5 years); Days to treatment end: 633 days (1.7 years); Number of cycles: 4; Treatment dose: 14,000 mg; Prescribed dose: 1770; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 643 days (1.8 years); Days to treatment end: 766 days (2.1 years); Number of cycles: 3; Treatment dose: 19,500 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Progressive Disease; Days to treatment start: 773 days (2.1 years); Days to treatment end: 794 days (2.2 years); Number of cycles: 2; Treatment dose: 100 mg/m2; Prescribed dose: 25; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 818 days (2.2 years); Days to treatment end: 845 days (2.3 years); Treatment dose: 3,000 cGy; Course number: 1; Number of fractions: 10; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Birinapant; Initial disease status: Progressive Disease; Days to treatment start: 903 days (2.5 years); Days to treatment end: 955 days (2.6 years); Number of cycles: 2; Treatment dose: 27 mg; Prescribed dose: 4.78; Prescribed dose units: mg; Route of administration: Intravenous.
2. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Larynx, NOS; Classification of tumor: Prior primary; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N2c; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Days to treatment start: -261 days; Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -252 days; Treatment anatomic sites: Locoregional Site.

Follow-up (3 entries)
- Days to follow up: 1,075 days (2.9 years); Disease response: With Tumor.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Adjuvant Therapy.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Preoperative.

Other clinical attributes
- DLCO (% of predicted): 134; FEV1/FVC before bronchodilator (%): 61; FEV1 before bronchodilator (% of reference): 86.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 25; Tobacco smoking onset year: 1983; Tobacco smoking quit year: 2006.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-60-2715-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.5; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-60-2715-01A-01-TS1: Section location: Top; Percent tumor cells: 67; Percent tumor nuclei: 75; Percent normal cells: 20; Percent necrosis: 3; Percent stromal cells: 10.
  Slide TCGA-60-2715-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 40; Percent necrosis: 5; Percent stromal cells: 5.
- Sample TCGA-60-2715-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-60-2715-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 2; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 4; Pharmaceutical therapy drug name: navelbine; Therapy regimen: Progression.
- Drug treatment 6: Regimen number: 5; Pharmaceutical therapy drug name: TL32711; Therapy regimen: Progression.
- Drug treatment 7: Regimen number: 3; Pharmaceutical therapy drug name: Tarceva; Therapy regimen: Progression.
- Drug treatment 7, Route of administrations: Route of administration: PO.
- Follow-up form: New tumor event diagnosis indicator: No; Tumor status: With tumor.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Larynx; Other malignancy histological type: Squamous Cell Carcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -357.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: Yes.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy of the larynx treated w/ chemotherapy and radiation.
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,075 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,075 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,075 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-60-2715-01): tumor purity 0.19, ploidy 1.93, whole-genome doublings 0 (call status: snp_call).
